Surgical pathology report (de-identified scan), TCGA case TCGA-RY-A845, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of California San Francisco, specimen TCGA-RY-A845-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Soc. Sec. #: [REDACTED]

Physician(s): [REDACTED]

Visit #: [REDACTED]

Sex: Female

Location: [REDACTED]

Accession #: [REDACTED]

Service Date: [REDACTED]

Received: [REDACTED]

Client: [REDACTED]

IID-0-3

FINAL PATHOLOGIC DIAGNOSIS

Oligoastrocytoma, grade II 9382/3
Site: CSF
Brain, supratentorial NOS C71.0
Brain, overlapping cereb. C71.0
path
4/10/2013

A. Brain, left parieto-occipital lobe, biopsy: Oligoastrocytoma, WHO grade II; see comment.

B. Brain, left parieto-occipital lobe, biopsy: Oligoastrocytoma, WHO grade II; see comment.

COMMENT:

This oligoastrocytoma is predominantly oligodendroglial and is composed of relatively uniform nuclei with only sparse mitoses. No foci of microvascular proliferation or necrosis are present. Immunohistochemistry for IDH1 (R132H mutant) protein, p53, and MIB1 was performed and evaluated on block A2. The neoplasm is positive for IDH1, and the MIB-1 labeling index is estimated at 6%. The p53 staining is estimated at 20% of tumor cells. Fluorescence in situ hybridization for 1p19q will be performed in the [REDACTED] and their report will be issued separately.

Intraoperative Diagnosis

FS1 (A) Brain, left parieto-occipital lobe, biopsy: Infiltrating glial neoplasm, favor oligoastrocytoma, WHO grade II. Tissue section and cytologic preparation.

Gross Description

The case is received in two parts, labeled with the patient's name and medical record number.

Part A is received fresh and additionally labeled "#1 left brain tumor - FS," and consists of three, unoriented, irregular fragments of tan-pink soft tissue (1 x 0.6 x 0.2 cm in aggregate). A portion of the fresh tissue is submitted for cytologic preparation. A portion of the fresh tissue is frozen and submitted as frozen section diagnosis 1, with the frozen section remnant submitted in cassette A1. The remaining fresh tissue is submitted in cassette A2.

Part B is received fresh and additionally labeled "left brain tumor," and consists of four, white-pink,

[page 2 of 2]
irregular, unoriented soft tissue fragments (3 x 2 x 0.7 cm in aggregate). The specimen is entirely submitted in cassettes B1-B2.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the
They have not been cleared or approved by the U. S. Food and Drug Administration.
The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Clinical History

The patient is a -year-old woman with an outside diagnosis of astrocytoma (not reviewed at). She has a left parieto-occipital non-enhancing brain mass concerning for a low-grade glioma. The patient undergoes a biopsy.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Pathology Resident

Signed: /Pathologist

Addendum

Date Ordered:
Date Complete:
Date Reported:

Status: Signed Out
By:

Addendum Comment

The Mib1 labeling index on B2 is estimated at approximately 5%.

Pathologist

Electronically signed out on

Criteria	W 10/8/13	Yes	No
SNAA Discrepancy			✓
Metastatic History			✓
Abnormalities Primary Noted			✓
Case Rechecked	QUANDED		

Source: NCI Genomic Data Commons file 215e3424-29bc-4592-8c8f-61418c37bb60 (TCGA-RY-A845.E4FBBEC7-8717-4D7D-B390-0BB242D05C2C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).